Gene-level copy-number profile of tumor specimen ALCH-B421-TTP1-A from ALCHEMIST case ALCH-B421, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.3 years (23,125 days).
Specimen ALCH-B421-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9dd8da29-7220-477f-af61-c8b7373997ca.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B421-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/5c492624-6003-45ae-84e3-737df3845c10

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 242; copy number 1: 7,385; copy number 2: 50,842; copy number 3: 69; copy number 4: 313; copy number 5: 35; copy number 7: 13; copy number 8: 4.

Homozygous deletions (total copy number 0; autosomes only): 207 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:16,155,211–16,161,883, 2 genes (within-gene range 0–1): AL451042.2, AL451042.1.
- chr1:22,563,489–22,633,366, 2 genes: EPHA8, MIR6127.
- chr1:28,505,943–28,539,300, 1 gene (within-gene range 0–1): RCC1.
- chr1:28,526,318–28,583,132, 9 genes: PRDX3P2, AL513497.1, TRNAU1AP, SNHG12, SNORD99, SNORA61, SNORA44, SNORA16A, SNORA16A.
- chr1:28,592,200–28,595,443, 1 gene (within-gene range 0–2): RAB42.
- chr2:25,227,855–25,342,590, 2 genes (within-gene range 0–2): DNMT3A, MIR1301.
- chr2:218,259,496–218,405,941, 14 genes: GPBAR1, AAMP, PNKD, TMBIM1, MIR6513, CATIP-AS2, MIR6810, RPL19P5, CATIP, CATIP-AS1, SLC11A1, CTDSP1, AC021016.2, MIR26B.
- chr2:231,706,895–231,713,551, 3 genes: PTMA, U4, MIR1244-1.
- chr2:232,349,754–232,548,115, 14 genes (within-gene range 0–2): ECEL1P3, AC068134.3, ALPP, AC068134.1, ECEL1P2, ALPG, ECEL1P1, AC068134.2, DIS3L2P1, ALPI, ECEL1, PRSS56, CHRND, CHRNG.
- chr2:241,808,312–241,812,016, 1 gene (within-gene range 0–2): AC131097.2.
- chr3:50,155,045–50,299,416, 15 genes (within-gene range 0–2): SEMA3F, AC104450.1, GNAT1, SLC38A3, GNAI2, MIR5787, U73169.1, U73166.1, SEMA3B-AS1, SEMA3B, MIR6872, LSMEM2, IFRD2, HYAL3, NAA80.
- chr7:2,558,972–2,775,500, 3 genes (within-gene range 0–2): IQCE, TTYH3, AMZ1.
- chr7:5,274,369–5,606,655, 14 genes: SLC29A4, TNRC18, AC093620.1, AC092171.1, AC092171.4, AC092171.3, AC092171.5, FBXL18, AC092171.2, MIR589, ACTB, AC006483.2, AC006483.1, FSCN1.
- chr7:6,497,462–6,658,279, 6 genes: GRID2IP, ZDHHC4, AC079742.1, C7orf26, ZNF853, ZNF316.
- chr7:56,991,888–57,020,273, 2 genes: TNRC18P3, SLC29A4P1.
- chr8:141,326,130–141,432,454, 6 genes: AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2, PTP4A3.
- chr8:141,434,545–141,437,954, 1 gene (within-gene range 0–2): AC100803.4.
- chr9:124,257,606–124,353,307, 3 genes (within-gene range 0–2): NEK6, AL162724.2, AL162724.1.
- chr10:25,244,061–25,244,854, 1 gene (within-gene range 0–2): AL354976.1.
- chr11:72,576,141–72,814,054, 14 genes: PDE2A, PDE2A-AS2, MIR139, RNU7-105P, PDE2A-AS1, ARAP1, ARAP1-AS1, AP003065.1, ARAP1-AS2, RPS12P20, STARD10, Y_RNA, MIR4692, AP002381.2.
- chr14:92,923,150–92,935,285, 1 gene: CHGA.
- chr14:99,583,017–99,625,740, 2 genes (within-gene range 0–2): Y_RNA, AL160313.1.
- chr15:25,169,337–25,257,027, 46 genes (within-gene range 0–2): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44, AC124303.1.
- chr16:75,218,988–75,268,053, 4 genes: CTRB1, AC009078.2, BCAR1, AC009078.3.
- chr16:83,899,115–84,045,333, 7 genes (within-gene range 0–2): MLYCD, AC009119.2, OSGIN1, NECAB2, SLC38A8, RNA5SP432, AC040169.4.
- chr16:89,912,119–89,972,832, 6 genes (within-gene range 0–1): MC1R, AC092143.1, AC092143.2, TUBB3, DEF8, CENPBD1.
- chr17:2,040,953–2,043,425, 3 genes: AC090617.10, OVCA2, AC090617.3.
- chr17:18,943,999–18,944,073, 1 gene: AC090286.2.
- chr17:18,951,625–18,954,149, 1 gene (within-gene range 0–2): AC090286.1.
- chr18:79,395,856–79,529,325, 6 genes (within-gene range 0–1): NFATC1, AC018445.3, AC018445.5, AC018445.1, AC018445.4, AC018445.2.
- chr20:32,443,059–32,743,567, 10 genes (within-gene range 0–2): NOL4L, AL034550.1, AL034550.3, AL034550.2, AL133343.2, NOL4L-DT, AL133343.1, C20orf203, FO393400.1, BAK1P1.
- chr21:43,358,147–43,366,566, 2 genes: LINC01679, AP001046.1.
- chr21:45,405,165–45,513,720, 4 genes (within-gene range 0–2): COL18A1, COL18A1-AS2, COL18A1-AS1, MIR6815.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 44 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:136,754,386–136,810,042, 7 genes, copy number 5 (within-gene range 3–5): LCN8, LCN15, ATP6V1G1P3, TMEM141, AL355987.3, CCDC183, AL355987.4.
- chr14:18,333,726–18,419,273, 4 genes, copy number 8: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr16:46,469,341–46,621,379, 5 genes, copy number 5: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1.
- chr18:23,957,754–24,397,880, 13 genes, copy number 5 (within-gene range 2–5): AC010754.1, TTC39C, TTC39C-AS1, AC090772.2, AC090772.1, RNU5A-6P, AC090772.4, CABYR, AC090772.3, OSBPL1A, RNA5SP452, Metazoa_SRP, RNU6-435P.
- chr21:10,413,477–13,120,807, 12 genes, copy number 7: BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr21:43,414,483–43,427,131, 1 gene, copy number 7: SIK1.
- chr21:43,461,960–43,479,534, 2 genes, copy number 5: LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 4,579. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
